Surgical pathology report (de-identified scan), TCGA case TCGA-W2-A7HF, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Medical College of Wisconsin, specimen TCGA-W2-A7HF-01A (Primary Tumor).

[page 1 of 5]
Results History

SURG PATH FINAL REPORT

Entry Information

Entry Date and Time

Lab Status
Final result

Entered by

Component Results

SURG PATH FINAL REPORT:

Accession #:

Specimen:

Date of Procedure:

Performing Clinician:

- A. Left adrenal
- B. Right adrenal
- C. ? parathyroid FS
- D. Left levels 3 and 4
- E. Thyroid and level 6 contents
- F. Right levels 3 and 4

Clinical Notes:

Pre-op diagnosis: Adrenal mass. A-B) Fresh tissue saved
for tissue bank.

Diagnosis:

- A. Left adrenal, adrenalectomy:
- Pheochromocytoma.
- Note: there is no evidence of capsular or vascular invasion by tumor.
- B. Right adrenal, adrenalectomy:
- Pheochromocytoma.
- Note: there is no evidence of capsular or vascular invasion by tumor.
- C. ? parathyroid:
- Small fragment of parathyroid tissue.
- D. Left levels 3 and 4, lymph nodes:
- Lymph nodes (1/13) involved with metastatic carcinoma.
- E. Thyroid and level 6 contents, total thyroidectomy:
- Medullary thyroid carcinoma, bilateral (see synoptic report).
- Note: special stains are in progress and will be reported in an addendum.
- Foci of nodular C-cell hyperplasia.
- Enlarged parathyroid gland (0.4 gm) consistent

ICD-O-3
Pheochromocytoma NOS
870010
Site @ Adrenal gland NOS
C74.9
JW 9/4/13

[page 2 of 5]
[REDACTED]

with parathyroid adenoma.

- Lymph nodes (0/4) free of tumor.

F. Right levels 3 and 4, lymph nodes:

Accession #:

- Lymph nodes (0/8), free of tumor.

(Electronically signed by)
Verified:

Tumor Characteristics:

E: Thyroid, Resection

SPECIMEN TYPE:

Total thyroidectomy

TUMOR SITE:

Right lobe

Left lobe

TUMOR FOCALITY:

Multifocal

TUMOR SIZE:

Greatest dimension: 3.2 cm

HISTOLOGIC TYPE:

Medullary carcinoma

MARGINS:

Margins uninvolved by carcinoma

LYMPH-VASCULAR INVASION:

Not identified

EXTRATHYROIDAL EXTENSION:

Not identified

PRIMARY TUMOR (pT):

pT2: Tumor more than 2 cm, but not more than 4 cm, limited to thyroid

REGIONAL LYMPH NODES (pN):

pN1b: Metastases to unilateral, bilateral or contralateral cervical or superior mediastinal lymph nodes

Number involved: 1

Number examined: 25

DISTANT METASTASIS (pM):

pMX: Cannot be assessed

*ADDITIONAL PATHOLOGIC FINDINGS:

None identified

Nodular C-cell hyperplasia

Gross:

[page 3 of 5]
[REDACTED]

A. The specimen is labeled "left adrenal." Received in formalin is a 244 gram, 12.0 x 8.0 x 4.4 cm, previously incised and disrupted piece of tissue with an aggregate of tissue measuring 9.0 x 5.0 x 1.5 cm. The tumor mass is tan-yellow and encapsulated. The mass is sectioned to reveal a tan-orange-pink cortex beneath the capsule and a dark brown

Accession #:

and soft stellate shaped medulla. Representative sections are submitted as follows:

Cassette Designation:

A1-5	Representative sections of
encapsulated mass	
A6-7	Representative sections of
additional tissue aggregate	

B. The specimen is labeled "right adrenal." Received fresh and transferred to formalin is a 54 gram, 5.2 x 4.3 x 3.2 cm, previously incised, encapsulated, tan-brown to orange mass. On sectioning, the mass appears to be completely stellate and tan-orange. Representative sections are submitted in cassettes B1 through B4.

C. The specimen is labeled "parathyroid." Received fresh for frozen section is a piece of tan-yellow tissue measuring 0.5 x 0.4 x 0.3 cm. The specimen is submitted in toto for frozen section. The frozen section remnant is resubmitted for permanent in cassette C.

D. The specimen is labeled "left levels 3 and 4." Received fresh and transferred to formalin is an 8.0 x 2.5 x 1.0 cm piece of fibrofatty tissue with multiple palpable nodules. Representative sections are submitted as follows:

Cassette Designation:

D1	One lymph node candidate, bisected
D2	Three lymph node candidates
D3	Four lymph node candidates
D4-6	Remaining fat, entirely submitted

E. The specimen is labeled "thyroid and level 6 contents." Received fresh and transferred to formalin is an intact thyroid with attached fibroadipose tissue and parathyroid candidate and separate mass of fibroadipose tissue measuring in aggregate of 6.5 x 8.0 x 3.5 cm. The thyroid and attached tissue is inked in black. The attached fibroadipose tissue and parathyroid candidate attached to the right inferior lobe are removed. The thyroid gland

[page 4 of 5]
[REDACTED]

weighs 36 grams and measures 7.0 x 5.0 x 2.5 cm. The surface of the thyroid is smooth and tan-brown. The thyroid is serially sectioned to reveal large, firm, pale nodules occupying the left and right lobes. The nodule in the left lobe measures 3.2 x 1.5 x 1.3 cm and contains an area of calcification towards its inferior edge. The nodule in the right lobe measures 3.0 x 1.5 x 1.4 cm and superiorly contains a smooth walled cyst. The parathyroid candidates

Accession #:

weigh 0.4 grams and measure 1.4 x 0.5 x 0.5 cm.
Representative sections are submitted as follows:

Cassette Designation:

E1-3	Representative sections of left
thyroid lobe nodule, E3	submitted after decal
E4	Representative sections of normal
left lobe thyroid	
E5-7	Representative sections of right
thyroid nodule	
E8	Representative sections of normal
right thyroid	
E9	Parathyroid candidates
E10	Four lymph node candidates

F. The specimen is labeled "right levels 3 and 4."
Received fresh and transferred to formalin is a piece of fibroadipose tissue measuring 6.5 x 3.5 x 1.0 cm.
Representative sections are submitted as follows:

Cassette Designation:

F1	One lymph node, bisected
F2	Three lymph node candidates
F3	Two lymph node candidates
F4	Two lymph node candidates

Intraoperative Consultation:

FROZEN SECTION:

C. Parathyroid tissue, 0.01 grams.

Microscopic:

Histological examinations have been performed on specimens A-F.

[REDACTED]

[page 5 of 5]
Administrative Notes:

CPT:

No charge codes are associated with this case.

Entry Information

Entry Date and Time

Lab Status
In process

Entered by

Criteria	W 8/29/13	Yes	No
Dual/Synchronous Primary Noted		/	Chc + Thyroid core: Normal
Reviewer Initials	SK	Case file viewed: 8/29/2013	

Source: NCI Genomic Data Commons file 675d7c5c-7db0-49ef-9e78-836ed9d5599a (TCGA-W2-A7HF.549ECDB9-29EB-4A9F-A768-4777EBDC448E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).